TARGET case TARGET-30-PARFRE — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other endocrine glands and related structures. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2660b19b-084d-59f8-b1b9-8323a46198ca

Demographics
Sex at birth: female; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C75.5; Tissue or organ of origin: Aortic body and other paraganglia; Classification of tumor: primary; Age at diagnosis: 0.2 years (60 days); Year of diagnosis: 2007; Days to last follow up: 2,451 days (6.7 years); Cog neuroblastoma risk group: Low Risk; INSS stage: Stage 4S.
   Pathology details: Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 2,451 days (6.7 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,451; Year of follow up: 2014.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PARFRE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PARFRE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 2451
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.46
- Histology: Favorable
- ICDO Description: Aortic body and other paraganglia Coccygeal body Coccygeal
